Surgical pathology report (de-identified scan), TCGA case TCGA-4V-A9QI, project TCGA-THYM (Thymoma), tissue source site Hospital Louis Pradel, specimen TCGA-4V-A9QI-01A (Primary Tumor).

Anterior mediastinal mass:

This is lymphoepithelial proliferation with lymphoid follicles along the septa or around perivascular spaces. Hassal bodies are seen. No necrosis is observed. In the periphery the tumor is encapsulated with minimal invasion in one area. The tumor is associated with normal thymus remnants with a normal ectopic parathyroid gland.

Left Internal mammary lymph node : this is follicular architecture without tumor invasion

Left paratracheal lymph nodes (4) : these are similar to the previous one

Preaortic lymph node: the aspect is similar to the previous nodes

Immunohistochemistry

Anti-pan k ratine AE1/AE3 and anti-cytok ratine 5/6: positive

Anti-EMA, anti-cytok ratine 20, anti-CD5, anti-CD20, and anti-CD57 : negative on tumor epithelial cells

Anti-CD3 and anti-CD1a : positive on the on tumoral lymphocytic proliferation, demonstrating its immature T phenotype

Conclusion :

- Thymoma, 6 cm in greatest dimension, histologic type B2, with minimal invasion, Masaoka Koga stage IIA, complete resection

ICD-O.3
Thymoma, type B2, malignant + 8584/3
Site ^{CASE} Thymus C37.9
^{path} mediastinum C38.3
Sp 4/2/14

Source: NCI Genomic Data Commons file 0f2d123d-5084-467a-ad2d-4a66fdb5255f (TCGA-4V-A9QI.8EF06119-8FF2-4C74-A8CD-373103E3102F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).